CCDI case PBBTYM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/43dc4f37-e32a-4fb4-8875-faa032759e97

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.8 years (4,322 days).

Biospecimens (4 samples)
- Sample 0DGX3V: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DGX3X, 0DGX3Z (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGZFI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
